Gene-level copy-number profile of tumor specimen TARGET-10-PASWFN-09A from TARGET case TARGET-10-PASWFN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.3 years (4,136 days).
Specimen TARGET-10-PASWFN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.7ac330ec-87d2-5fe5-9872-52ffa50206c6.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PASWFN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate.
https://portal.gdc.cancer.gov/files/29409495-6b04-4a73-9a9f-b7f29a176c8a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 545; copy number 1: 2,101; copy number 2: 57,542; copy number 3: 53; copy number 4: 32.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:140,577,845–140,579,657, 2 genes: AC108019.2, RN7SL152P.
- chr11:55,935,456–56,055,730, 9 genes: OR5I1, OR10AF1P, OR10AK1P, OR10AG1, OR7E5P, OR5F1, OR5F2P, OR5AS1, OR5AQ1P.
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.
- chr12:23,108,458–23,108,493, 1 gene: AC087258.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 246. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
